CCDI case PBCLIN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/43774ddc-9c67-4d19-8a52-1cc4f776d18f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Prostate gland; Age at diagnosis: 9.9 years (3,627 days).

Biospecimens (4 samples)
- Samples 0DUNOA, 0DUNPW (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUNP2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVBRN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
